Gene-level copy-number profile of tumor specimen TCGA-PA-A5YG-01A from TCGA case TCGA-PA-A5YG, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 51.8 years (18,926 days).
Specimen TCGA-PA-A5YG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.0aac83d9-dfb0-4aa8-9fc4-b12acef7fdee.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-PA-A5YG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7302d3ce-d96f-4693-a80a-75a62e79a316

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 2: 42,532; copy number 3: 202; copy number 4: 17,066.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-PA-A5YG-01A-11D-A29H-01): tumor purity 0.73, ploidy 1.27, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:1,597,177–1,837,521, 19 genes: KRTAP5-2, KRTAP5-3, KRTAP5-4, KRTAP5-5, AP006285.1, FAM99A, FAM99B, LINC02708, KRTAP5-6, IFITM10, AC068580.4, CTSD, AC068580.3, AC068580.1, AC068580.5, AC068580.2, RPL36AP39, AC139143.1, SYT8.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
